Somatic mutation profile of tumor specimen TARGET-10-PARAYM-09A (aliquot TARGET-10-PARAYM-09A-01D) from TARGET case TARGET-10-PARAYM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.2 years (5,569 days).
Specimen TARGET-10-PARAYM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60eaa84c-df57-4793-b93c-d3f7b1730fe6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARAYM-10A (Blood Derived Normal), aliquot TARGET-10-PARAYM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfaa3e13-99d3-43bf-b825-841afefda5bf

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Frame Shift Ins 5, Intron 3, RNA 3, Silent 2, 5'UTR 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTK | c.1328T>C p.I443T | Missense Mutation (SNP) | VAF 47/49 reads (96%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs782133950, COSV58122891; called by muse, mutect2, varscan2
- C11orf53 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as rs376710383; called by muse, mutect2, varscan2
- CAMSAP3 | c.2486C>T p.A829V | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs765553330, COSV50349551; called by muse, varscan2
- DSC3 | c.592A>T p.T198S | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV64574781; called by muse, mutect2, varscan2
- G0S2 | c.119delinsCC p.L40Pfs*79 | Frame Shift Ins (INS) | VAF 22/74 reads (30%) | catalogued as COSV65433245; called by mutect2*, pindel, varscan2*
- KRT78 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as COSV58853110; called by muse, mutect2
- MTCL1 | c.2212del p.R738Vfs*68 (on ENST00000306329 / NM_001378206.1; = p.R378Vfs*68 on NM_015210.4) | Frame Shift Del (DEL) | VAF 33/64 reads (52%) | catalogued as COSV60410329; called by mutect2, pindel, varscan2
- NOTCH1 | c.4721T>C p.L1574P | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024760, COSV53072929; called by muse, mutect2, varscan2
- OSBP2 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs370162841; called by muse, mutect2, varscan2
- PDZD8 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57827858; called by muse, mutect2, varscan2
- PER1 | c.3172G>A p.A1058T | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); catalogued as rs1185403493, COSV57921492; called by muse, mutect2, varscan2
- PGR | c.623C>A p.A208D | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.657); catalogued as COSV54797247, COSV54808566; called by muse, mutect2, varscan2
- RYR3 | c.8615G>A p.S2872N (on ENST00000389232; = p.S2873N on NM_001036.6) | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754341540, COSV66804664; called by muse, mutect2, varscan2
- USP7 | c.1240_1241insTACCT p.Q414Lfs*58 | Frame Shift Ins (INS) | VAF 17/45 reads (38%) | catalogued as COSV61216864; called by mutect2, pindel*, varscan2
- G0S2 | c.118dup p.L40Pfs*79 | Frame Shift Ins (INS) | VAF 22/58 reads (38%) | called by mutect2, varscan2
- HDGF | c.149dup p.G51Rfs*63 | Frame Shift Ins (INS) | VAF 16/33 reads (48%) | called by mutect2, varscan2
- IGHV3-20 | chr14:106210933 GTGTCT>A | Missense Mutation (DEL) | VAF 43/80 reads (54%) | called by pindel, varscan2*
- LEF1 | c.553dup p.S185Ffs*8 | Frame Shift Ins (INS) | VAF 18/43 reads (42%) | called by mutect2, pindel, varscan2
- ABCC2 | c.4581C>T p.P1527= | Silent (SNP) | VAF 69/160 reads (43%) | catalogued as rs1564704231; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLITRK5 | c.1752C>T p.G584= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV61524092; called by muse, mutect2, varscan2
- AC108676.1 | n.140G>A | RNA (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- ADD1 | c.1605+75T>C | Intron (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- CD177P1 | n.605T>C | RNA (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2
- CD177P1 | n.604G>C | RNA (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2
- GRHL1 | c.20+1150C>T | Intron (SNP) | VAF 49/86 reads (57%) | catalogued as rs1364913539; called by muse, mutect2, varscan2
- MIR7-3 | chr19:4769409 C>A | 5'Flank (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- RPL41 | c.-76G>T | 5'UTR (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- SPATA13 | c.-222-26529C>T | Intron (SNP) | VAF 27/68 reads (40%) | catalogued as rs1287671138, COSV66070996; called by muse, mutect2, varscan2
